Gene-level copy-number profile of tumor specimen TCGA-D8-A1X6-01A from TCGA case TCGA-D8-A1X6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 80.1 years (29,256 days).
Specimen TCGA-D8-A1X6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ed8ece0b-e4c8-4789-be92-e5ef0f0e6af2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1X6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7f4ae60-0db2-4d02-ac6d-4affe7888616

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 584; copy number 2: 1,253; copy number 3: 14,430; copy number 4: 37,453; copy number 5: 55; copy number 6: 71; copy number 7: 3,045; copy number 8: 523; copy number 9: 883; copy number 11: 84; copy number 12: 1,434.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1X6-01A-11D-A14J-01): tumor purity 0.66, ploidy 4.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,401 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,929,479–145,066,685, 1,591 genes, copy number 9–12 (broad region; genes not listed).
- chr16:11,555–22,288,738, 810 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 584. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
